Somatic mutation profile of tumor specimen 0DBHZA from CCDI case PBBLHR, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Primary diagnosis: Medulloblastoma, NOS; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 10.1 years (3,672 days).
Specimen 0DBHZA: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) bbd43e15-8551-4a32-ada8-3ff836b2ddb9.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DBHZ8 (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/62203aa1-1b48-471f-9039-c995aa3fdb9b

The open-access MAF lists 23 somatic variants for this specimen: 20 protein-altering or splice-affecting, 2 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 16, Nonsense Mutation 3, Silent 2, Translation Start Site 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ARID1A | c.5164C>T p.R1722* | Nonsense Mutation (SNP) | VAF 40/764 reads (5%) | hotspot (GDC flag); catalogued as rs1485978447, COSV61371609; ClinVar: pathogenic; called by muse, mutect2
- DDX3X | c.973C>T p.R325C (on ENST00000399959; = p.R326C on NM_001356.5) | Missense Mutation (SNP) | VAF 314/395 reads (79%) | SIFT deleterious (0.04); PolyPhen benign (0.091); catalogued as rs1555953548, COSV67863531; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- ARHGEF10 | c.604G>A p.E202K (on ENST00000398564; = p.E177K on NM_014629.4) | Missense Mutation (SNP) | VAF 39/760 reads (5%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.17); catalogued as rs1313394089; called by muse, mutect2
- CSMD3 | c.6173C>T p.P2058L (on ENST00000297405 / NM_001363185.1; = p.P1954L on NM_052900.3) | Missense Mutation (SNP) | VAF 52/545 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.679); catalogued as COSV52105504; called by muse, mutect2
- CXCL11 | c.217C>T p.R73* | Nonsense Mutation (SNP) | VAF 231/596 reads (39%) | catalogued as rs149207110; called by muse, mutect2, varscan2
- DDX3X | c.1137G>C p.M379I (on ENST00000399959; = p.M380I on NM_001356.5) | Missense Mutation (SNP) | VAF 30/268 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV67863682, COSV67864048; called by muse, mutect2, varscan2
- DNAH2 | c.730C>T p.R244W | Missense Mutation (SNP) | VAF 60/840 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs370337265; called by muse, mutect2
- F2 | c.814G>A p.V272M | Missense Mutation (SNP) | VAF 204/505 reads (40%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.602); catalogued as rs199558597, COSV61315325, COSV61317795; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- LRP1B | c.6718C>T p.R2240* | Nonsense Mutation (SNP) | VAF 33/490 reads (7%) | catalogued as COSV101254260; called by muse, mutect2
- MAP2K6 | c.361C>T p.R121W | Missense Mutation (SNP) | VAF 176/718 reads (25%) | SIFT deleterious (0.05); PolyPhen probably damaging (1); catalogued as rs779399972; called by muse, mutect2, varscan2
- NDRG1 | c.73G>A p.G25S | Missense Mutation (SNP) | VAF 360/931 reads (39%) | SIFT tolerated (0.66); PolyPhen benign (0); catalogued as rs377527660, COSV60485866; called by muse, mutect2, varscan2
- NIPA1 | c.896C>T p.T299M | Missense Mutation (SNP) | VAF 53/495 reads (11%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.721); catalogued as rs756976675; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- OR2B11 | c.754G>A p.V252I | Missense Mutation (SNP) | VAF 97/229 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.917); catalogued as rs368268590, COSV100275578, COSV59509504; called by muse, mutect2, varscan2
- RPL22 | c.1A>T p.M1? | Translation Start Site (SNP) | VAF 320/714 reads (45%) | SIFT deleterious (0.01); PolyPhen benign (0); catalogued as COSV52377337, COSV52377608; called by mutect2, varscan2
- VPS13D | c.2579G>A p.R860H | Missense Mutation (SNP) | VAF 54/620 reads (9%) | SIFT tolerated (0.1); PolyPhen benign (0.336); catalogued as rs915499110, COSV50672484; called by muse, mutect2
- ADAM28 | c.968T>C p.V323A | Missense Mutation (SNP) | VAF 111/257 reads (43%) | SIFT deleterious (0); PolyPhen benign (0.13); called by muse, mutect2, varscan2
- C17orf80 | c.843C>G p.S281R | Missense Mutation (SNP) | VAF 28/860 reads (3%) | SIFT deleterious (0.05); PolyPhen benign (0.003); called by muse, mutect2
- GLCE | c.881T>C p.I294T | Missense Mutation (SNP) | VAF 54/768 reads (7%) | SIFT deleterious (0); PolyPhen benign (0.11); called by muse, mutect2
- ITGA2B | c.1981G>C p.V661L | Missense Mutation (SNP) | VAF 74/872 reads (8%) | SIFT tolerated (0.48); PolyPhen benign (0.046); called by muse, mutect2
- ZNF316 | c.959G>A p.R320Q | Missense Mutation (SNP) | VAF 253/574 reads (44%) | SIFT tolerated (0.22); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- FREM1 | c.5925T>C p.S1975= | Silent (SNP) | VAF 243/524 reads (46%) | called by muse, mutect2, varscan2
- GALNT17 | c.1551C>T p.T517= | Silent (SNP) | VAF 232/633 reads (37%) | catalogued as rs149074490; called by muse, mutect2, varscan2
- LGALS14 | c.16-718G>A | Intron (SNP) | VAF 175/347 reads (50%) | catalogued as rs370541317; called by muse, mutect2, varscan2
